CPTAC case C3N-05108 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/15cdb343-6066-486a-8084-8d5a7ba5130a

Demographics
Sex at birth: female; Race: white; Year of birth: 1946; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 73.9 years (26,980 days); Year of diagnosis: 2020; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4b; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,185 days (3.2 years); Progression or recurrence: yes; Days to last follow up: 1,185 days (3.2 years); Clark level: III; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 1.7 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 21; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 408 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 824 days (2.3 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,185 days (3.2 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1984; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-05108-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 53 days; Initial weight: 210 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-05108-24: Section location: Trunk; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-05108-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 53 days; Method of sample procurement: Blood Draw.
